Somatic mutation profile of tumor specimen 0DH9LU from CCDI case PBBUIB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,130 days).
Specimen 0DH9LU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68f72cf2-eb08-4ff5-a69e-8c48eabfdd8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH9KY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5634c7af-170b-4f38-b398-4be33ad59a36

The open-access MAF lists 38 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Intron 3, 3'UTR 2, 5'UTR 2, Frame Shift Ins 1, RNA 1, Nonsense Mutation 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.4789C>T p.R1597W | Missense Mutation (SNP) | VAF 135/300 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782819520; called by muse, mutect2, varscan2
- DMTN | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs770419665; called by muse, mutect2, varscan2
- DNAH5 | c.1673C>T p.T558I | Missense Mutation (SNP) | VAF 117/493 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.148); catalogued as rs1056112557; called by muse, mutect2, varscan2
- GREB1L | c.2955G>T p.Q985H | Missense Mutation (SNP) | VAF 103/581 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99338439; called by muse, mutect2, varscan2
- ITIH5 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 115/346 reads (33%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.543); catalogued as COSV99904585; called by muse, mutect2, varscan2
- LAMA2 | c.6260C>T p.S2087F | Missense Mutation (SNP) | VAF 108/371 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs1299914386; called by muse, mutect2, varscan2
- LTN1 | c.2354-7dup | Splice Region (INS) | VAF 44/193 reads (23%) | catalogued as rs758084053; called by mutect2, varscan2
- MICALL2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 516/776 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201639803; called by muse, mutect2, varscan2
- NPR1 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 158/575 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as rs149008713; called by muse, mutect2, varscan2
- RHBDF2 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 102/709 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs780242428; called by muse, mutect2, varscan2
- SGIP1 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 138/523 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs767772421; called by muse, mutect2, varscan2
- TNFRSF11A | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 121/480 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as rs757983626, COSV54025565; called by muse, mutect2, varscan2
- AHCTF1 | c.5713dup p.R1905Kfs*4 (on ENST00000366508; = p.R1879Kfs*4 on NM_015446.5) | Frame Shift Ins (INS) | VAF 104/470 reads (22%) | called by mutect2, varscan2
- DCSTAMP | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 100/233 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK10 | c.2397G>T p.Q799H | Missense Mutation (SNP) | VAF 115/522 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FSTL4 | c.261C>A p.C87* | Nonsense Mutation (SNP) | VAF 121/644 reads (19%) | called by muse, mutect2, varscan2
- H2AC11 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ITPR2 | c.4441G>A p.E1481K | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MOXD1 | c.1300T>A p.L434I | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- NALCN | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 175/572 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- OR4C46 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TSNAXIP1 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBAL3 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAGEE1 | c.1128G>A p.S376= | Silent (SNP) | VAF 176/383 reads (46%) | catalogued as rs782472224, COSV63910991; called by muse, mutect2, varscan2
- NFATC1 | c.1437G>T p.G479= | Silent (SNP) | VAF 121/733 reads (17%) | called by muse, mutect2, varscan2
- OR4K1 | c.384G>A p.K128= | Silent (SNP) | VAF 75/439 reads (17%) | catalogued as rs748748659; called by muse, mutect2, varscan2
- SDK2 | c.3588G>A p.E1196= | Silent (SNP) | VAF 47/625 reads (8%) | catalogued as rs778143441; called by muse, mutect2
- SLC26A3 | c.1956C>T p.D652= | Silent (SNP) | VAF 293/977 reads (30%) | called by muse, mutect2, varscan2
- USP54 | c.4947C>A p.S1649= | Silent (SNP) | VAF 62/240 reads (26%) | called by muse, mutect2, varscan2
- CDYL | c.186+41887C>A | Intron (SNP) | VAF 47/82 reads (57%) | called by muse, mutect2, varscan2
- COL25A1-DT | n.1045A>G | RNA (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- KRT80 | c.-100G>A | 5'UTR (SNP) | VAF 42/150 reads (28%) | catalogued as rs1023147731; called by muse, mutect2, varscan2
- LEKR1 | c.*866G>C | 3'UTR (SNP) | VAF 44/186 reads (24%) | catalogued as COSV100739305; called by muse, mutect2, varscan2
- MTMR3 | c.294-66G>A | Intron (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- OPRPN | c.51+216A>G | Intron (SNP) | VAF 64/317 reads (20%) | called by muse, mutect2, varscan2
- OR2L2 | c.*50A>G | 3'UTR (SNP) | VAF 44/168 reads (26%) | called by muse, mutect2, varscan2
- PRPS1L1 | c.-7G>T | 5'UTR (SNP) | VAF 73/486 reads (15%) | called by muse, mutect2, varscan2
- SLC25A13 | chr7:96119089 G>A | 3'Flank (SNP) | VAF 71/358 reads (20%) | called by muse, mutect2, varscan2
